Somatic mutation profile of tumor specimen TCGA-05-4249-01A (aliquot TCGA-05-4249-01A-01D-1105-08) from TCGA case TCGA-05-4249, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 67.2 years (24,532 days).
Specimen TCGA-05-4249-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e1a5102c-e7b6-49fd-b4a2-32a10936ab55.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-05-4249-10A (Blood Derived Normal), aliquot TCGA-05-4249-10A-01D-1105-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/082e03c5-f49f-455e-9e6d-b477b962deca

The open-access MAF lists 340 somatic variants for this specimen: 274 protein-altering or splice-affecting, 63 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 228, Silent 63, Nonsense Mutation 26, Frame Shift Del 8, Splice Site 7, Frame Shift Ins 3, 5'UTR 2, Intron 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 8/23 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- MYF6 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 47/172 reads (27%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.742); catalogued as rs747205109, COSV57353234; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 5/20 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCC2 | c.4273G>T p.G1425W | Missense Mutation (SNP) | VAF 83/254 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64988502; called by muse, mutect2, varscan2
- ABI3BP | c.2084C>A p.P695Q | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.372); catalogued as COSV99427825; called by muse, mutect2
- AC126283.2 | c.58G>C p.V20L | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV67099883; called by muse, mutect2, varscan2
- ADAM2 | c.1270G>T p.G424C | Missense Mutation (SNP) | VAF 77/269 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55868056; called by muse, mutect2, varscan2
- ADAM23 | c.1718G>T p.C573F | Missense Mutation (SNP) | VAF 69/254 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52229364; called by muse, mutect2, varscan2
- ADAM9 | c.1049G>T p.G350V | Missense Mutation (SNP) | VAF 56/174 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65962372; called by muse, mutect2, varscan2
- ADAMTS12 | c.3047C>A p.P1016Q | Missense Mutation (SNP) | VAF 34/213 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV61255008; called by muse, mutect2, varscan2
- ADAMTS5 | c.2674G>C p.D892H | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53184963; called by muse, mutect2, varscan2
- ADGRL2 | c.793G>C p.D265H | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV54662946, COSV54684897, COSV54688211; called by muse, mutect2, varscan2
- ADPRM | c.211C>T p.Q71* | Nonsense Mutation (SNP) | VAF 46/118 reads (39%) | catalogued as COSV65755371; called by muse, mutect2, varscan2
- ALDOB | c.383T>A p.L128H | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV66398594; called by muse, mutect2, varscan2
- ALG13 | c.2903G>A p.C968Y | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV52644876; called by muse, mutect2, varscan2
- ALPK1 | c.3153G>T p.W1051C | Missense Mutation (SNP) | VAF 84/237 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV51591757; called by muse, mutect2, varscan2
- ANGPT1 | c.1481G>A p.R494Q | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs377442517, COSV52434515; called by muse, mutect2, varscan2
- ANLN | c.3064G>A p.D1022N | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56079324; called by muse, mutect2
- APOB | c.6365C>A p.A2122D | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs988496277, COSV51951383; called by muse, mutect2, varscan2
- ARHGAP31 | c.3588G>T p.Q1196H | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51798646; called by muse, mutect2, varscan2
- ARID3C | c.159G>T p.E53D | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.039); catalogued as COSV66698409; called by muse, mutect2, varscan2
- ARMC3 | c.1040C>A p.S347* | Nonsense Mutation (SNP) | VAF 22/69 reads (32%) | catalogued as COSV53067400; called by muse, mutect2, varscan2
- ASIC4 | c.68C>A p.A23E | Missense Mutation (SNP) | VAF 56/239 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV61733386; called by muse, mutect2, varscan2
- ASTN2 | c.1442G>A p.S481N (on ENST00000313400 / NM_001365069.1; = p.S430N on NM_014010.5) | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.92); PolyPhen possibly damaging (0.531); catalogued as rs746045893, COSV57816120; called by muse, mutect2, varscan2
- ATP10D | c.1694G>T p.R565L | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs781238830, COSV56712940, COSV56713092; called by muse, mutect2, varscan2
- ATP6V0B | c.68G>T p.G23V | Missense Mutation (SNP) | VAF 174/578 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.047); catalogued as COSV52545284; called by muse, mutect2, varscan2
- ATP8A2 | c.1663-1G>C p.X555_splice | Splice Site (SNP) | VAF 29/87 reads (33%) | catalogued as COSV54975790, COSV99684804; called by muse, mutect2
- ATP8B2 | c.2749A>T p.M917L (on ENST00000672630; = p.M884L on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 90/1420 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59248822; called by muse, mutect2
- BIRC7 | c.675G>T p.Q225H | Missense Mutation (SNP) | VAF 73/135 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.146); catalogued as COSV53903249; called by muse, mutect2, varscan2
- BNC2 | c.1978C>A p.P660T | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV66156698; called by muse, mutect2, varscan2
- BRAF | c.2405C>A p.A802E (on ENST00000288602 / NM_001374244.1; = p.A762E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 207/427 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV56115442, COSV56368837; called by muse, mutect2, varscan2
- C8orf74 | c.493G>T p.E165* | Nonsense Mutation (SNP) | VAF 27/91 reads (30%) | catalogued as COSV58755524; called by muse, mutect2, varscan2
- CACNA1H | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.65); PolyPhen benign (0.257); catalogued as rs766768686, COSV61988218; called by muse, mutect2, varscan2
- CANX | c.1366G>T p.G456C | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV56006833; called by muse, mutect2, varscan2
- CAVIN4 | c.1034A>T p.K345I | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV56868315; called by muse, mutect2, varscan2
- CCDC171 | c.3125T>G p.L1042R | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV52652579; called by muse, mutect2, varscan2
- CCN3 | c.720G>T p.Q240H | Missense Mutation (SNP) | VAF 61/253 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV52385272; called by muse, mutect2, varscan2
- CCT8L2 | c.1384G>C p.D462H | Missense Mutation (SNP) | VAF 78/300 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.4); catalogued as COSV63463726; called by muse, mutect2, varscan2
- CCT8L2 | c.1286G>A p.R429K | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63463626, COSV63463732; called by muse, varscan2
- CCT8L2 | c.1213G>C p.D405H | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV63463735; called by muse, varscan2
- CCT8L2 | c.162C>A p.H54Q | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV63463749; called by muse, mutect2, varscan2
- CDH7 | c.1231G>T p.V411L | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.074); catalogued as COSV59894152; called by muse, mutect2, varscan2
- CEMIP2 | c.3414G>T p.R1138S | Missense Mutation (SNP) | VAF 67/179 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV65489156, COSV65489415; called by muse, mutect2, varscan2
- CEP152 | c.4711T>C p.C1571R (on ENST00000380950 / NM_001194998.2; = p.C1515R on NM_014985.4) | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV57864585; called by muse, mutect2, varscan2
- CFAP74 | c.4443C>G p.F1481L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as rs768973631, COSV60587959; called by muse, mutect2, varscan2
- CMTM5 | c.182C>A p.A61D | Missense Mutation (SNP) | VAF 84/239 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV59305468; called by muse, mutect2, varscan2
- COL12A1 | c.5515G>T p.G1839C | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59407426; called by muse, mutect2, varscan2
- COL4A5 | c.404G>T p.G135V | Missense Mutation (SNP) | VAF 71/112 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60371502; called by muse, mutect2, varscan2
- COPS2 | c.272G>C p.R91T | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as rs1433446000, COSV54647447, COSV54647574; called by muse, mutect2, varscan2
- CPQ | c.224G>T p.G75V | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55140923, COSV55160023; called by muse, mutect2, varscan2
- CRNKL1 | c.655G>T p.E219* | Nonsense Mutation (SNP) | VAF 30/112 reads (27%) | catalogued as COSV55646613; called by muse, mutect2, varscan2
- CROCC | c.919C>T p.R307W | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1270080650, COSV65014770; called by muse, mutect2, varscan2
- CSF1R | c.2429T>C p.I810T | Missense Mutation (SNP) | VAF 90/230 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV53842712; called by muse, mutect2, varscan2
- CSMD3 | c.8429C>A p.T2810N (on ENST00000297405 / NM_001363185.1; = p.T2641N on NM_052900.3) | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.91); catalogued as COSV52159788, COSV52252067; called by muse, mutect2, varscan2
- CSMD3 | c.1993G>C p.G665R (on ENST00000297405 / NM_001363185.1; = p.G561R on NM_052900.3) | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52106949, COSV52310826; called by muse, mutect2, varscan2
- CSMD3 | c.1336C>A p.H446N | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as COSV52123784, COSV52310846; called by muse, mutect2, varscan2
- CTDNEP1 | c.103-2A>T p.X35_splice | Splice Site (SNP) | VAF 28/67 reads (42%) | catalogued as COSV100021095; called by muse, mutect2, varscan2
- DAG1 | c.1697A>G p.D566G | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.53); catalogued as COSV58187062; called by muse, mutect2, varscan2
- DCST2 | c.1174C>T p.P392S | Missense Mutation (SNP) | VAF 28/298 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV55054461; called by muse, mutect2
- DDX11 | c.1543T>A p.Y515N | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV99299978; called by muse, mutect2, varscan2
- DIP2B | c.556T>G p.S186A | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.265); catalogued as COSV56591772; called by muse, mutect2, varscan2
- DIS3L2 | c.1187G>T p.C396F | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV56051853; called by muse, mutect2, varscan2
- DLGAP2 | c.901G>T p.D301Y | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70099083, COSV70103668; called by muse, mutect2, varscan2
- DOCK3 | c.4109A>G p.N1370S | Missense Mutation (SNP) | VAF 74/273 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV56548679; called by muse, mutect2, varscan2
- DOP1B | c.4270A>T p.I1424F | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV67695991; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1069A>G p.R357G (on ENST00000361735 / NM_015935.5; = p.R271G on NM_014955.3) | Missense Mutation (SNP) | VAF 8/121 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as rs923452637, COSV62283198; called by muse, mutect2
- EHBP1L1 | c.1478G>A p.G493D | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1233508172, COSV58574998; called by muse, mutect2, varscan2
- EIF2B4 | c.917G>T p.R306L (on ENST00000347454 / NM_001034116.2; = p.R305L on NM_015636.3) | Missense Mutation (SNP) | VAF 83/294 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV52010320; called by muse, mutect2, varscan2
- EMC9 | c.177G>C p.M59I | Missense Mutation (SNP) | VAF 65/264 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as COSV99246376; called by muse, mutect2, varscan2
- EPRS1 | c.2026G>A p.G676R | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65101457; called by muse, mutect2
- ETS2 | c.962C>T p.S321F | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.107); catalogued as COSV62874335; called by mutect2, varscan2
- FAT3 | c.2455A>G p.I819V | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53170890; called by muse, mutect2, varscan2
- FAT4 | c.2184A>G p.I728M | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs1263838787, COSV67899309; called by muse, mutect2, varscan2
- FBH1 | c.1289C>T p.P430L (on ENST00000362091 / NM_178150.3; = p.P481L on NM_032807.4) | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV62984419; called by muse, mutect2, varscan2
- FBXO27 | c.358G>T p.G120C | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs377322565; called by muse, mutect2, varscan2
- FBXO38 | c.1492G>T p.D498Y | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.47); catalogued as rs748833930, COSV57029950, COSV57031319; called by muse, mutect2, varscan2
- FCRL2 | c.787C>A p.P263T | Missense Mutation (SNP) | VAF 160/398 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.314); catalogued as COSV63835039; called by muse, mutect2, varscan2
- FHDC1 | c.476C>T p.S159F | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52602829; called by muse, mutect2, varscan2
- FIBIN | c.212A>T p.Q71L | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.052); catalogued as COSV100590492; called by muse, mutect2, varscan2
- FLG | c.10252G>T p.A3418S | Missense Mutation (SNP) | VAF 123/984 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.347); catalogued as COSV64248519; called by muse, mutect2, varscan2
- FNDC8 | c.69C>A p.N23K | Missense Mutation (SNP) | VAF 19/200 reads (10%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); catalogued as COSV50104449; called by muse, mutect2
- FST | c.168C>A p.C56* | Nonsense Mutation (SNP) | VAF 29/88 reads (33%) | catalogued as COSV56816792; called by muse, mutect2, varscan2
- GAN | c.565G>T p.V189F | Missense Mutation (SNP) | VAF 96/172 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs766484755, COSV101666432, COSV73720760; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GAS2L3 | c.317G>C p.R106T | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV57159021; called by muse, mutect2, varscan2
- GC | c.352G>T p.E118* | Nonsense Mutation (SNP) | VAF 32/118 reads (27%) | catalogued as COSV56739748; called by muse, mutect2, varscan2
- GIMAP2 | c.196G>T p.G66* | Nonsense Mutation (SNP) | VAF 47/72 reads (65%) | catalogued as COSV99785440, COSV99785572; called by muse, mutect2, varscan2
- GIP | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 24/222 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.115); catalogued as COSV62467882; called by muse, mutect2, varscan2
- GPC6 | c.320-2A>T p.X107_splice | Splice Site (SNP) | VAF 26/72 reads (36%) | catalogued as COSV100989489; called by muse, mutect2, varscan2
- GPR22 | c.1248T>A p.F416L | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.95); PolyPhen benign (0.067); catalogued as COSV51763797; called by muse, mutect2, varscan2
- GPS1 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs866017121, COSV57648396; called by muse, mutect2, varscan2
- GRM1 | c.2555C>A p.T852N | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51308827; called by muse, mutect2, varscan2
- HAL | c.1307G>T p.G436V | Missense Mutation (SNP) | VAF 46/193 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.048); catalogued as COSV54120257; called by muse, mutect2, varscan2
- HELQ | c.2658G>T p.W886C | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55027866; called by muse, mutect2, varscan2
- HERC2 | c.10106G>T p.G3369V | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs755062921, COSV99875407; called by muse, mutect2, varscan2
- HERC2 | c.10105G>T p.G3369C | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99875412; called by muse, mutect2, varscan2
- HMCN1 | c.11831A>G p.Y3944C | Missense Mutation (SNP) | VAF 81/128 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758772278, COSV54939401; called by muse, mutect2, varscan2
- HNF4A | c.869A>C p.K290T | Missense Mutation (SNP) | VAF 53/222 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV57388963; called by muse, mutect2, varscan2
- HOXB4 | c.356C>A p.P119Q | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV60178992; called by muse, mutect2, varscan2
- IGKV6D-41 | c.217C>A p.Q73K | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs1026641395; called by muse, mutect2, varscan2
- IMPG2 | c.2032G>T p.E678* | Nonsense Mutation (SNP) | VAF 17/43 reads (40%) | catalogued as COSV51985441; called by muse, mutect2, varscan2
- ITGA2 | c.1612G>T p.G538C | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.357); catalogued as rs1378008008, COSV56866177; called by muse, mutect2, varscan2
- ITIH2 | c.622C>T p.H208Y | Missense Mutation (SNP) | VAF 74/289 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV64435139; called by muse, mutect2, varscan2
- KCNC2 | c.1649C>T p.P550L | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs142936560; called by muse, varscan2
- KIAA1755 | c.1631C>T p.A544V | Missense Mutation (SNP) | VAF 46/188 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.515); catalogued as COSV54080460; called by muse, mutect2, varscan2
- KIF6 | c.1914G>T p.K638N | Missense Mutation (SNP) | VAF 53/319 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.056); catalogued as COSV54693555; called by muse, mutect2, varscan2
- KLB | c.121C>A p.L41M | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); catalogued as COSV99962340; called by muse, mutect2, varscan2
- KLB | c.122T>A p.L41Q | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV99962341; called by muse, mutect2, varscan2
- KLHL1 | c.1385A>G p.Y462C | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1246569130, COSV64783372; called by muse, mutect2, varscan2
- KMT2D | c.14309C>T p.P4770L | Missense Mutation (SNP) | VAF 96/362 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.057); catalogued as COSV56484626; called by muse, mutect2, varscan2
- KRT33B | c.856C>A p.L286M | Missense Mutation (SNP) | VAF 57/277 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV52442132, COSV52442361; called by muse, mutect2, varscan2
- KRTAP11-1 | c.174G>C p.E58D | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV100190738; called by muse, mutect2, varscan2
- KRTAP13-3 | c.12C>A p.N4K | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.673); catalogued as COSV61880266; called by muse, mutect2, varscan2
- L3MBTL2 | c.710A>T p.Q237L | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); catalogued as COSV53435667; called by muse, mutect2
- LAMA2 | c.4286G>T p.C1429F | Missense Mutation (SNP) | VAF 72/217 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70354689; called by muse, mutect2, varscan2
- LCN9 | c.209G>T p.S70I | Missense Mutation (SNP) | VAF 73/196 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99479659; called by muse, mutect2, varscan2
- LGR5 | c.2543G>T p.S848I | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.231); catalogued as COSV57002027, COSV57009755; called by muse, mutect2, varscan2
- LHFPL1 | c.659C>A p.P220H | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); catalogued as COSV64334142; called by muse, mutect2, varscan2
- LILRA1 | c.517C>A p.R173S | Missense Mutation (SNP) | VAF 90/334 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0.011); catalogued as COSV52184752; called by muse, mutect2, varscan2
- LILRA2 | c.810G>T p.Q270H | Missense Mutation (SNP) | VAF 60/187 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52196497; called by muse, mutect2, varscan2
- LIN37 | c.508G>A p.G170R | Missense Mutation (SNP) | VAF 49/170 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV50001296; called by muse, mutect2, varscan2
- LRP1B | c.1409-2A>T p.X470_splice | Splice Site (SNP) | VAF 8/31 reads (26%) | catalogued as COSV67272325; called by muse, mutect2, varscan2
- LRRIQ1 | c.2654T>A p.I885N | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV101280640; called by muse, mutect2, varscan2
- MATN1 | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 40/143 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); catalogued as rs567114277, COSV65651398; called by muse, mutect2, varscan2
- MDN1 | c.587G>C p.C196S | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV65529966; called by muse, mutect2, varscan2
- MED13L | c.6498A>T p.L2166F | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56129713; called by muse, mutect2, varscan2
- MED25 | c.1206G>T p.W402C | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100457705; called by muse, mutect2, varscan2
- MKRN3 | c.379G>T p.A127S | Missense Mutation (SNP) | VAF 53/158 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as COSV58812042; called by muse, mutect2, varscan2
- MPDZ | c.2288G>T p.S763I | Missense Mutation (SNP) | VAF 76/299 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1404647512, COSV59953289; called by muse, mutect2, varscan2
- MS4A4A | c.272C>T p.T91I | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV59703290; called by muse, mutect2, varscan2
- MTREX | c.1568G>C p.R523P | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57929094, COSV57929975, COSV57931651; called by muse, mutect2, varscan2
- MTSS2 | c.580C>T p.R194W | Missense Mutation (SNP) | VAF 24/282 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778297929, COSV58699896; called by muse, mutect2
- MUC16 | c.24514C>A p.L8172I | Missense Mutation (SNP) | VAF 48/180 reads (27%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.138); catalogued as rs1568805989, COSV67491773; called by muse, mutect2, varscan2
- MYEOV | c.601G>T p.V201L | Missense Mutation (SNP) | VAF 79/258 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.182); catalogued as COSV58295291; called by muse, mutect2, varscan2
- MYH11 | c.3667G>A p.D1223N | Missense Mutation (SNP) | VAF 85/706 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV55568909; called by muse, mutect2, varscan2
- MYH15 | c.2853G>T p.R951S | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.059); catalogued as COSV56319200; called by muse, mutect2, varscan2
- MYL2 | c.32G>T p.G11V | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV57408052; called by muse, mutect2, varscan2
- MYO15A | c.1444C>T p.R482* | Nonsense Mutation (SNP) | VAF 36/89 reads (40%) | catalogued as rs867369805, COSV52765541; called by muse, mutect2, varscan2
- MYO1H | c.790G>T p.D264Y | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV60450752; called by muse, mutect2, varscan2
- NALCN | c.3037G>T p.G1013C | Missense Mutation (SNP) | VAF 41/165 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51918505, COSV51963952; called by muse, mutect2, varscan2
- NEB | c.5033A>T p.N1678I | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV51458687; called by muse, mutect2, varscan2
- NEFM | c.450C>A p.Y150* | Nonsense Mutation (SNP) | VAF 9/30 reads (30%) | catalogued as COSV99647455; called by muse, mutect2
- NEK9 | c.1351G>T p.G451* | Nonsense Mutation (SNP) | VAF 22/81 reads (27%) | catalogued as COSV53132391, COSV53133503; called by muse, mutect2, varscan2
- NELL1 | c.1273G>A p.V425I | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV54322661; called by muse, mutect2, varscan2
- NEURL1 | c.215C>T p.S72F | Missense Mutation (SNP) | VAF 95/317 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100872803; called by muse, mutect2, varscan2
- NGFR | c.449C>A p.P150H | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV50804246; called by muse, mutect2, varscan2
- NIPAL2 | c.308G>T p.G103V | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57843270; called by muse, mutect2, varscan2
- NLGN2 | c.659-1G>T p.X220_splice | Splice Site (SNP) | VAF 79/219 reads (36%) | catalogued as COSV57211977; called by muse, mutect2, varscan2
- NLRP7 | c.1442C>G p.A481G | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as COSV60181613; called by muse, mutect2, varscan2
- NOP56 | c.1454A>C p.Q485P | Missense Mutation (SNP) | VAF 190/495 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as COSV61391484; called by muse, mutect2
- NOS1AP | c.595+1G>C p.X199_splice | Splice Site (SNP) | VAF 53/89 reads (60%) | catalogued as COSV62639993; called by muse, mutect2, varscan2
- NRXN1 | c.3563G>T p.G1188V | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.519); catalogued as COSV100640716, COSV60521309; called by muse, mutect2, varscan2
- OLA1 | c.77G>T p.G26V | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52974047; called by muse, mutect2, varscan2
- OR10J1 | c.437T>A p.L146Q | Missense Mutation (SNP) | VAF 165/294 reads (56%) | SIFT tolerated (0.29); PolyPhen benign (0.125); catalogued as COSV71128523; called by muse, mutect2, varscan2
- OR10J3 | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs1337149635, COSV59955610; called by muse, mutect2
- OR13C2 | c.707A>T p.K236I | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73377789; called by muse, mutect2, varscan2
- OR2T29 | c.123G>C p.K41N | Missense Mutation (SNP) | VAF 100/256 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100148312; called by muse, mutect2
- OR4F15 | c.372G>A p.M124I | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs1170971856, COSV59970263; called by muse, mutect2, varscan2
- OR5A2 | c.381C>G p.I127M | Missense Mutation (SNP) | VAF 4/69 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV57391854; called by muse, mutect2
- PARP14 | c.2900T>A p.V967D | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV71735538; called by muse, mutect2, varscan2
- PCDHA12 | c.1739T>A p.L580* | Nonsense Mutation (SNP) | VAF 58/193 reads (30%) | catalogued as COSV56543358; called by muse, mutect2, varscan2
- PCDHA2 | c.1451C>A p.A484E | Missense Mutation (SNP) | VAF 46/178 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.688); catalogued as rs782310227, COSV65367654, COSV65370923; called by muse, mutect2, varscan2
- PCDHGA10 | c.635A>G p.H212R | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); catalogued as COSV54027091; called by muse, mutect2, varscan2
- PCDHGB7 | c.220C>A p.H74N | Missense Mutation (SNP) | VAF 41/145 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as COSV53978763, COSV54027108; called by muse, mutect2, varscan2
- PCNX1 | c.4223C>G p.P1408R | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV53101478; called by muse, mutect2, varscan2
- PDE6B | c.910C>A p.R304S | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.657); catalogued as COSV55330688; called by muse, mutect2, varscan2
- PLEK | c.329C>A p.A110D | Missense Mutation (SNP) | VAF 103/327 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.255); catalogued as COSV52253890; called by muse, mutect2, varscan2
- PLEKHA7 | c.1370G>T p.R457L | Missense Mutation (SNP) | VAF 44/211 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV63043518; called by muse, varscan2
- PLEKHN1 | c.337A>T p.S113C | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100379215; called by muse, mutect2, varscan2
- POLQ | c.4892G>C p.W1631S | Missense Mutation (SNP) | VAF 55/196 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV51760845, COSV99951324; called by muse, mutect2, varscan2
- POP4 | c.292C>G p.L98V | Missense Mutation (SNP) | VAF 54/203 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.104); catalogued as COSV55677416; called by muse, mutect2, varscan2
- POPDC3 | c.418A>C p.K140Q | Missense Mutation (SNP) | VAF 56/209 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.226); catalogued as COSV54646145; called by muse, mutect2, varscan2
- POTED | c.493G>T p.D165Y | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV55051157; called by muse, mutect2, varscan2
- PPP3R1 | c.292A>G p.I98V | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.6); PolyPhen benign (0.037); catalogued as rs369235532; called by muse, mutect2, varscan2
- PRRC2B | c.1286G>C p.R429P | Missense Mutation (SNP) | VAF 48/174 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV61936106, COSV61942793; called by muse, mutect2, varscan2
- PRSS36 | c.977G>T p.G326V | Missense Mutation (SNP) | VAF 62/192 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51639646; called by muse, mutect2, varscan2
- PSAP | c.1297C>A p.L433M | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV56488364; called by muse, mutect2, varscan2
- PSG7 | c.1100C>A p.T367K | Missense Mutation (SNP) | VAF 98/351 reads (28%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.953); catalogued as COSV68446555; called by muse, mutect2, varscan2
- RASA2 | c.2113C>T p.R705* | Nonsense Mutation (SNP) | VAF 8/45 reads (18%) | catalogued as rs773436247, COSV53945957; called by muse, mutect2, varscan2
- RBM48 | c.856A>G p.R286G | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56003713; called by muse, mutect2, varscan2
- RELN | c.9774C>A p.C3258* | Nonsense Mutation (SNP) | VAF 46/85 reads (54%) | catalogued as COSV59032606; called by muse, mutect2, varscan2
- RFX3 | c.1528C>G p.R510G | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV56524622; called by muse, mutect2, varscan2
- RIMS2 | c.2594C>A p.P865H (on ENST00000666250 / NM_001348490.2; = p.P673H on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs764351498, COSV51721872; called by muse, mutect2, varscan2
- RMDN1 | c.432T>A p.Y144* | Nonsense Mutation (SNP) | VAF 32/71 reads (45%) | catalogued as COSV52210509; called by muse, mutect2, varscan2
- ROBO2 | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.993); catalogued as rs760139372, COSV59936835; called by muse, mutect2, varscan2
- RP1L1 | c.1394C>A p.S465* | Nonsense Mutation (SNP) | VAF 21/130 reads (16%) | catalogued as COSV66759970; called by muse, mutect2, varscan2
- RPAP2 | c.1114G>C p.E372Q | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV72509635; called by muse, mutect2, varscan2
- RTN4IP1 | c.1177A>T p.I393F | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV100954208; called by muse, mutect2, varscan2
- RYR2 | c.3109C>T p.L1037F | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.915); catalogued as COSV63712245; called by muse, varscan2
- SAV1 | c.458A>G p.H153R | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV100220833; called by muse, mutect2, varscan2
- SCN3A | c.1859G>A p.R620Q | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.758); catalogued as COSV51809286; called by muse, mutect2, varscan2
- SDE2 | c.175A>G p.S59G | Missense Mutation (SNP) | VAF 21/262 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as rs530108297, COSV55253147; called by muse, mutect2
- SERPINE1 | c.145G>T p.A49S | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (0.93); PolyPhen benign (0.009); catalogued as COSV56171394; called by muse, mutect2, varscan2
- SHANK1 | c.2522C>A p.P841H | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.891); catalogued as COSV53261647; called by muse, mutect2, varscan2
- SIPA1L2 | c.1886C>T p.T629M | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as rs780220404, COSV53390854, COSV99479294; called by muse, varscan2
- SLC22A11 | c.857A>T p.K286M | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.013); catalogued as COSV57254992; called by muse, mutect2, varscan2
- SLC44A4 | c.212C>T p.T71I | Missense Mutation (SNP) | VAF 164/517 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.091); catalogued as rs1272354074, COSV57669068; called by muse, mutect2, varscan2
- SLC51A | c.288G>A p.T96= | Splice Region (SNP) | VAF 27/152 reads (18%) | catalogued as rs139345051; called by muse, mutect2, varscan2
- SLC9A4 | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV54838981; called by muse, mutect2, varscan2
- SLITRK5 | c.2723A>G p.D908G | Missense Mutation (SNP) | VAF 43/329 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as COSV61526076; called by muse, mutect2, varscan2
- SLTM | c.859G>T p.A287S | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV51057734; called by muse, mutect2, varscan2
- SMARCA2 | c.3091G>C p.E1031Q | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV61812397; called by muse, mutect2, varscan2
- SON | c.1027C>T p.P343S | Missense Mutation (SNP) | VAF 58/196 reads (30%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.085); catalogued as COSV51670256; called by muse, mutect2, varscan2
- SON | c.1765G>T p.V589L | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.633); catalogued as COSV51670278; called by muse, mutect2, varscan2
- SPECC1 | c.3170A>T p.Q1057L | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as COSV54965941; called by muse, mutect2, varscan2
- SPTA1 | c.4141G>T p.E1381* | Nonsense Mutation (SNP) | VAF 164/321 reads (51%) | catalogued as COSV63758945; called by muse, mutect2, varscan2
- SPTB | c.6922C>A p.P2308T | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV55983735; called by muse, mutect2, varscan2
- STAB1 | c.5191G>A p.A1731T | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as rs762362511, COSV58742714; called by muse, mutect2, varscan2
- STK36 | c.2786C>T p.A929V | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.764); catalogued as COSV55330441; called by muse, mutect2, varscan2
- STK36 | c.3173C>T p.S1058F | Missense Mutation (SNP) | VAF 136/462 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as COSV55325498; called by muse, mutect2, varscan2
- SULT1C3 | c.853T>C p.F285L | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.798); catalogued as COSV61254646; called by muse, mutect2, varscan2
- SUPT6H | c.2446A>T p.K816* | Nonsense Mutation (SNP) | VAF 52/110 reads (47%) | catalogued as COSV58931341; called by muse, mutect2, varscan2
- SV2C | c.364G>T p.E122* | Nonsense Mutation (SNP) | VAF 23/74 reads (31%) | catalogued as COSV59228600; called by muse, mutect2, varscan2
- SYNM | c.4628C>T p.S1543L (on ENST00000336292 / NM_145728.3; = p.S1231L on NM_015286.6) | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV50444263; called by muse, mutect2, varscan2
- TAF1A | c.15T>A p.S5R | Missense Mutation (SNP) | VAF 23/266 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.839); catalogued as COSV61919801; called by muse, mutect2
- TCTEX1D1 | c.235G>T p.V79F | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as COSV51076895; called by muse, mutect2, varscan2
- TENM2 | c.6536A>G p.Y2179C (on ENST00000518659 / NM_001122679.2; = p.Y1940C on NM_001080428.3) | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69140625; called by muse, mutect2, varscan2
- TENM3 | c.4553A>C p.D1518A | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV69318679; called by muse, mutect2, varscan2
- TEX15 | c.2432A>T p.N811I (on ENST00000256246; = p.N1194I on NM_001350162.2) | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.352); catalogued as COSV56353310; called by muse, mutect2, varscan2
- THAP12 | c.689G>T p.C230F | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.082); catalogued as COSV52613015; called by muse, mutect2, varscan2
- TINAG | c.599T>A p.M200K | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV52514738; called by muse, mutect2, varscan2
- TJP1 | c.3645G>T p.E1215D | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.01); catalogued as COSV62046382; called by muse, mutect2, varscan2
- TLR8 | c.1360C>T p.R454* (on ENST00000218032 / NM_138636.5; = p.R472* on NM_016610.4) | Nonsense Mutation (SNP) | VAF 45/76 reads (59%) | catalogued as COSV54320469; called by muse, mutect2, varscan2
- TNFSF11 | c.907C>T p.Q303* | Nonsense Mutation (SNP) | VAF 55/167 reads (33%) | catalogued as COSV53479850; called by muse, mutect2, varscan2
- TNR | c.3149G>T p.S1050I | Missense Mutation (SNP) | VAF 113/183 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV54912223; called by muse, mutect2, varscan2
- TNR | c.599C>T p.S200L | Missense Mutation (SNP) | VAF 48/441 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs1178257247, COSV54883758; called by muse, mutect2, varscan2
- TRAPPC8 | c.2464G>T p.A822S | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.718); catalogued as COSV51977107; called by muse, mutect2, varscan2
- TREML2 | c.859G>T p.G287W | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101530183; called by muse, mutect2
- TRPA1 | c.207T>A p.Y69* | Nonsense Mutation (SNP) | VAF 9/41 reads (22%) | catalogued as COSV51573615; called by muse, mutect2, varscan2
- TRPC5 | c.2453C>A p.P818Q | Missense Mutation (SNP) | VAF 97/160 reads (61%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.044); catalogued as COSV53302368, COSV99462636; called by muse, mutect2, varscan2
- TRPM3 | c.4481C>A p.P1494H (on ENST00000357533 / NM_001366142.2; = p.P1349H on NM_020952.6) | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.525); catalogued as COSV62594324; called by muse, mutect2, varscan2
- TRPM3 | c.2656G>T p.G886* (on ENST00000357533 / NM_001366142.2; = p.G729* on NM_020952.6) | Nonsense Mutation (SNP) | VAF 33/89 reads (37%) | catalogued as COSV100677897, COSV62594334; called by muse, mutect2, varscan2
- TSSK4 | c.597T>A p.C199* | Nonsense Mutation (SNP) | VAF 110/356 reads (31%) | catalogued as COSV99841799; called by muse, mutect2, varscan2
- TTC37 | c.1129G>T p.D377Y | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.423); catalogued as COSV100706744; called by muse, mutect2, varscan2
- TTLL2 | c.525C>A p.Y175* | Nonsense Mutation (SNP) | VAF 50/162 reads (31%) | catalogued as COSV53443700; called by muse, mutect2, varscan2
- TTN | c.86602T>A p.S28868T (on ENST00000591111; = p.S21444T on NM_003319.4) | Missense Mutation (SNP) | VAF 9/37 reads (24%) | PolyPhen probably damaging (0.991); catalogued as COSV60331677; called by muse, mutect2, varscan2
- TTN | c.82514T>A p.V27505D (on ENST00000591111; = p.V20081D on NM_003319.4) | Missense Mutation (SNP) | VAF 49/333 reads (15%) | PolyPhen benign (0.049); catalogued as COSV60331734; called by muse, mutect2, varscan2
- TTN | c.46769G>T p.S15590I (on ENST00000591111; = p.S8166I on NM_003319.4) | Missense Mutation (SNP) | VAF 53/201 reads (26%) | PolyPhen possibly damaging (0.654); catalogued as COSV60331790; called by muse, mutect2, varscan2
- TUT1 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 32/200 reads (16%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV53469870; called by muse, mutect2, varscan2
- USH2A | c.12440C>A p.P4147H | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.237); catalogued as COSV56431936; called by muse, mutect2, varscan2
- USP48 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 30/203 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57610579; called by muse, mutect2, varscan2
- USP54 | c.4895G>A p.R1632Q | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.859); catalogued as rs577546144, COSV60447790; called by muse, mutect2, varscan2
- UTRN | c.5900G>T p.R1967L | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as COSV62332209, COSV62347377; called by muse, mutect2, varscan2
- YEATS2 | c.14A>T p.K5M | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV59372219; called by muse, mutect2, varscan2
- ZBBX | c.98T>A p.V33E | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV100284646, COSV56800919; called by muse, mutect2, varscan2
- ZFP36L1 | c.277G>T p.E93* | Nonsense Mutation (SNP) | VAF 27/120 reads (23%) | catalogued as COSV60547146; called by muse, mutect2, varscan2
- ZMYM1 | c.1679A>T p.N560I | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.893); catalogued as COSV63253603; called by muse, mutect2, varscan2
- ZNF19 | c.49G>C p.E17Q | Missense Mutation (SNP) | VAF 25/197 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as COSV55508978; called by muse, mutect2, varscan2
- ZNF208 | c.3470G>T p.S1157I | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.029); catalogued as COSV68112228; called by muse, mutect2, varscan2
- ZNF227 | c.2051G>T p.G684V | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1258545606, COSV57313659; called by muse, mutect2, varscan2
- ZNF286A | c.1330G>T p.G444W | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67846414; called by muse, mutect2, varscan2
- ZNF320 | c.1238A>G p.Y413C | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101206900; called by muse, mutect2, varscan2
- ZNF416 | c.535G>T p.D179Y | Missense Mutation (SNP) | VAF 45/154 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV52185770; called by muse, mutect2, varscan2
- ZNF460 | c.572C>T p.P191L | Missense Mutation (SNP) | VAF 64/200 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV64416411; called by muse, mutect2, varscan2
- ZNF483 | c.1813A>G p.K605E | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58517198; called by muse, mutect2, varscan2
- ZNF490 | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.094); catalogued as rs1427151460, COSV58482709; called by muse, mutect2, varscan2
- ZNF527 | c.472A>G p.T158A | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs746246081, COSV62229483; called by muse, mutect2, varscan2
- ZNF536 | c.880_881insT p.R294Lfs*79 | Frame Shift Ins (INS) | VAF 55/226 reads (24%) | catalogued as COSV100835516; called by mutect2, pindel, varscan2
- ZNF646 | c.5269C>T p.R1757W | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs752986217, COSV54925607; called by muse, varscan2
- ZNF780B | c.806G>T p.S269I | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV55468046; called by muse, mutect2, varscan2
- CBX4 | c.1291C>T p.R431C | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CCNQ | c.428del p.K143Sfs*14 | Frame Shift Del (DEL) | VAF 68/143 reads (48%) | called by mutect2, pindel, varscan2
- COL5A3 | c.4017dup p.G1340Rfs*9 | Frame Shift Ins (INS) | VAF 13/48 reads (27%) | called by mutect2, pindel, varscan2
- FOXJ1 | c.465_466del p.F155Lfs*43 | Frame Shift Del (DEL) | VAF 5/48 reads (10%) | called by mutect2, pindel
- FRK | c.542_544del p.R181del | In Frame Del (DEL) | VAF 22/168 reads (13%) | called by pindel, varscan2
- ISCA1 | c.245dup p.R83Qfs*21 | Frame Shift Ins (INS) | VAF 20/130 reads (15%) | called by mutect2, pindel, varscan2
- KIR3DL3 | c.376del p.L126Sfs*9 | Frame Shift Del (DEL) | VAF 92/361 reads (25%) | called by mutect2, pindel, varscan2
- NBPF11 | c.1019C>G p.S340C | Missense Mutation (SNP) | VAF 42/656 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); called by muse, mutect2
- OBSCN | c.20309del p.P6770Hfs*9 | Frame Shift Del (DEL) | VAF 50/106 reads (47%) | called by mutect2, pindel, varscan2
- PBLD | c.556_572del p.Q186Efs*10 | Frame Shift Del (DEL) | VAF 24/172 reads (14%) | called by mutect2, pindel, varscan2
- RPH3A | c.275del p.G92Efs*4 (on ENST00000389385 / NM_001143854.2; = p.G88Efs*4 on NM_014954.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 61/230 reads (27%) | called by mutect2, pindel, varscan2
- RUNDC1 | c.1517del p.G506Efs*12 | Frame Shift Del (DEL) | VAF 63/166 reads (38%) | called by mutect2, pindel, varscan2
- SPATA31A3 | c.2856G>T p.R952S | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.015); called by mutect2, varscan2
- TAF2 | c.1701_1706delinsTAGCT p.V568Sfs*4 | Frame Shift Del (DEL) | VAF 26/208 reads (13%) | called by pindel, varscan2*
- ZSWIM5 | c.1609+1del p.X537_splice | Splice Site (DEL) | VAF 33/124 reads (27%) | called by mutect2, pindel, varscan2
- ADAMTS12 | c.819C>A p.T273= | Silent (SNP) | VAF 29/98 reads (30%) | catalogued as COSV61278645; called by muse, mutect2, varscan2
- ADGRB3 | c.147T>A p.P49= | Silent (SNP) | VAF 57/127 reads (45%) | catalogued as COSV65382114, COSV65418581; called by muse, mutect2, varscan2
- APOBEC3F | c.693C>G p.V231= | Silent (SNP) | VAF 34/249 reads (14%) | catalogued as COSV57911827; called by muse, mutect2, varscan2
- ARID2 | c.3414G>T p.G1138= | Silent (SNP) | VAF 44/172 reads (26%) | catalogued as COSV57614151; called by muse, mutect2, varscan2
- ARMC5 | c.1812T>C p.D604= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as rs528087546, COSV51659787; called by muse, mutect2, varscan2
- ARMC9 | c.1458C>G p.L486= | Silent (SNP) | VAF 18/186 reads (10%) | catalogued as COSV63023554; called by muse, mutect2
- ASB7 | c.708C>T p.Y236= | Silent (SNP) | VAF 22/125 reads (18%) | catalogued as rs376420227; called by muse, mutect2, varscan2
- BCAS3 | c.2616G>T p.R872= (on ENST00000390652 / NM_001353144.2; = p.R857= on NM_017679.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as COSV66781723; called by muse, mutect2
- BCO1 | c.1389G>A p.A463= | Silent (SNP) | VAF 69/189 reads (37%) | catalogued as rs183103921, COSV50727937; called by muse, mutect2, varscan2
- BECN1 | c.918T>C p.A306= | Silent (SNP) | VAF 29/127 reads (23%) | catalogued as COSV100162148; called by muse, mutect2, varscan2
- BRINP2 | c.645C>A p.I215= | Silent (SNP) | VAF 38/70 reads (54%) | catalogued as rs528002829, COSV64177063, COSV64180092; called by muse, mutect2, varscan2
- C1orf216 | c.117C>G p.A39= | Silent (SNP) | VAF 28/151 reads (19%) | catalogued as COSV99231245; called by muse, mutect2, varscan2
- CCDC88C | c.2586G>C p.L862= | Silent (SNP) | VAF 33/205 reads (16%) | catalogued as COSV66241449; called by muse, mutect2, varscan2
- CCL23 | c.297T>G p.G99= | Silent (SNP) | VAF 18/83 reads (22%) | called by muse, mutect2, varscan2
- CCT8L2 | c.1065G>C p.L355= | Silent (SNP) | VAF 58/228 reads (25%) | catalogued as COSV63463745; called by muse, varscan2
- CENPF | c.405A>T p.A135= | Silent (SNP) | VAF 19/147 reads (13%) | catalogued as COSV65278881; called by muse, mutect2, varscan2
- CNR2 | c.552A>T p.P184= | Silent (SNP) | VAF 15/94 reads (16%) | catalogued as COSV100991537; called by muse, mutect2, varscan2
- COL6A2 | c.1593C>G p.G531= | Silent (SNP) | VAF 10/144 reads (7%) | catalogued as COSV100153916; called by muse, mutect2
- DCAF16 | c.399G>T p.R133= | Silent (SNP) | VAF 86/252 reads (34%) | catalogued as COSV66384383; called by muse, mutect2, varscan2
- DDX11 | c.1542G>T p.R514= | Silent (SNP) | VAF 21/105 reads (20%) | catalogued as COSV99299975; called by muse, mutect2, varscan2
- DENND2A | c.321G>A p.E107= | Silent (SNP) | VAF 171/342 reads (50%) | catalogued as COSV52058576; called by muse, mutect2, varscan2
- DIAPH3 | c.939A>T p.S313= (on ENST00000400324 / NM_001042517.2; = p.S50= on NM_030932.3) | Silent (SNP) | VAF 18/160 reads (11%) | catalogued as COSV57380618; called by muse, mutect2, varscan2
- DNAH17 | c.639C>A p.A213= | Silent (SNP) | VAF 35/224 reads (16%) | catalogued as COSV101102893; called by muse, mutect2, varscan2
- DSCAML1 | c.1074C>T p.N358= (on ENST00000321322; = p.N298= on NM_020693.4) | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV58402177; called by muse, mutect2, varscan2
- EXOC3 | c.966G>T p.R322= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV59268639; called by muse, mutect2
- GABBR1 | c.2166C>T p.V722= | Silent (SNP) | VAF 39/148 reads (26%) | catalogued as COSV63544430; called by muse, mutect2, varscan2
- GCNT1 | c.732G>T p.T244= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as COSV65058761, COSV65059152; called by muse, mutect2, varscan2
- KCNK17 | c.246C>T p.V82= | Silent (SNP) | VAF 48/192 reads (25%) | catalogued as COSV100949262; called by muse, mutect2, varscan2
- LRBA | c.3564A>T p.S1188= | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as COSV63964373; called by muse, mutect2, varscan2
- MDGA2 | c.1530A>T p.P510= (on ENST00000399232 / NM_001113498.2; = p.P212= on NM_182830.4) | Silent (SNP) | VAF 27/73 reads (37%) | catalogued as COSV62114415; called by muse, mutect2, varscan2
- MICAL3 | c.3756G>T p.T1252= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as COSV101490925; called by muse, mutect2, varscan2
- MROH2B | c.4089T>C p.C1363= | Silent (SNP) | VAF 35/139 reads (25%) | catalogued as COSV68189250; called by muse, mutect2, varscan2
- MYH1 | c.3817C>T p.L1273= | Silent (SNP) | VAF 36/114 reads (32%) | catalogued as COSV56856771; called by muse, mutect2, varscan2
- NKPD1 | c.1251T>C p.R417= | Silent (SNP) | VAF 3/11 reads (27%) | called by muse, mutect2
- OR2AG1 | c.159C>A p.A53= | Silent (SNP) | VAF 80/256 reads (31%) | catalogued as COSV100264918; called by muse, mutect2, varscan2
- OR2AG1 | c.160C>A p.R54= | Silent (SNP) | VAF 78/255 reads (31%) | catalogued as COSV100264923; called by muse, mutect2, varscan2
- OR51D1 | c.732G>T p.R244= | Silent (SNP) | VAF 70/245 reads (29%) | catalogued as COSV62914307, COSV62914817; called by muse, mutect2, varscan2
- PARVB | c.423C>T p.S141= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as rs758000622, COSV58690446; called by muse, mutect2, varscan2
- PAX7 | c.1389C>A p.G463= | Silent (SNP) | VAF 19/130 reads (15%) | catalogued as COSV64752706; called by muse, mutect2, varscan2
- PCDH7 | c.2472G>T p.G824= | Silent (SNP) | VAF 25/143 reads (17%) | called by muse, mutect2, varscan2
- PCDHB16 | c.2208G>T p.L736= | Silent (SNP) | VAF 45/239 reads (19%) | catalogued as COSV53370726; called by muse, mutect2, varscan2
- PCLO | c.2121G>A p.V707= | Silent (SNP) | VAF 18/113 reads (16%) | catalogued as COSV100427325, COSV61644214; called by muse, mutect2, varscan2
- PLCE1 | c.582C>T p.D194= | Silent (SNP) | VAF 19/93 reads (20%) | catalogued as rs1436504571, COSV53371142; called by muse, mutect2, varscan2
- PLG | c.600C>A p.T200= | Silent (SNP) | VAF 31/81 reads (38%) | catalogued as rs766015667, COSV51986332; called by muse, mutect2, varscan2
- PLIN4 | c.2550C>G p.T850= (on ENST00000301286; = p.T865= on NM_001367868.2) | Silent (SNP) | VAF 67/218 reads (31%) | catalogued as COSV100013709; called by muse, varscan2
- RNASE11 | c.366C>A p.R122= | Silent (SNP) | VAF 22/87 reads (25%) | catalogued as COSV60088184; called by muse, mutect2, varscan2
- ROBO2 | c.1584G>T p.P528= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as rs779025170, COSV59936847; called by muse, mutect2, varscan2
- SIGLEC6 | c.120G>T p.T40= | Silent (SNP) | VAF 13/121 reads (11%) | catalogued as COSV58435467, COSV58437344; called by muse, mutect2, varscan2
- SLITRK1 | c.1354C>T p.L452= | Silent (SNP) | VAF 55/202 reads (27%) | catalogued as COSV65677481; called by muse, mutect2, varscan2
- SPOCK3 | c.1206G>A p.E402= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV62736447; called by muse, mutect2, varscan2
- STRN3 | c.1944A>T p.V648= (on ENST00000357479 / NM_001083893.2; = p.V564= on NM_014574.4) | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV100670782; called by muse, mutect2, varscan2
- TAGLN2 | c.492T>C p.D164= | Silent (SNP) | VAF 39/324 reads (12%) | catalogued as COSV57423595; called by muse, mutect2, varscan2
- TEAD1 | c.462G>A p.P154= | Silent (SNP) | VAF 21/191 reads (11%) | catalogued as rs752862372, COSV57567740; called by muse, mutect2, varscan2
- THBS2 | c.261G>T p.T87= | Silent (SNP) | VAF 43/193 reads (22%) | catalogued as COSV64682088; called by muse, mutect2, varscan2
- THBS4 | c.2448G>A p.T816= | Silent (SNP) | VAF 18/102 reads (18%) | catalogued as rs751672404, COSV63469291; called by muse, mutect2, varscan2
- TLL2 | c.72G>T p.G24= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV63575690; called by muse, mutect2, varscan2
- TPO | c.126C>A p.V42= | Silent (SNP) | VAF 34/124 reads (27%) | catalogued as COSV61108759, COSV61110613; called by muse, mutect2, varscan2
- TRIP10 | c.1584G>A p.T528= (on ENST00000313244 / NM_001288962.2; = p.T472= on NM_004240.4) | Silent (SNP) | VAF 21/163 reads (13%) | catalogued as rs1007568691, COSV55584793; called by muse, mutect2, varscan2
- UBE2J2 | c.306G>T p.P102= | Silent (SNP) | VAF 71/240 reads (30%) | catalogued as COSV59573834; called by muse, mutect2, varscan2
- UNC79 | c.4830A>G p.L1610= (on ENST00000393151 / NM_001346218.2; = p.L1433= on NM_020818.5) | Silent (SNP) | VAF 58/164 reads (35%) | catalogued as COSV56409161; called by muse, mutect2, varscan2
- VCAM1 | c.21G>T p.V7= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as COSV54121815; called by muse, mutect2, varscan2
- WAS | c.762C>A p.P254= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV64997702; called by muse, mutect2, varscan2
- ZNF646 | c.5146C>T p.L1716= | Silent (SNP) | VAF 54/446 reads (12%) | catalogued as COSV54926564; called by muse, varscan2
- GPR139 | c.-1C>A | 5'UTR (SNP) | VAF 16/32 reads (50%) | catalogued as COSV100429956; called by muse, mutect2
- IGLV2-8 | c.-9G>A | 5'UTR (SNP) | VAF 4/28 reads (14%) | catalogued as rs769555342; called by muse, mutect2
- TTN | c.10361-4086C>A | Intron (SNP) | VAF 41/145 reads (28%) | catalogued as COSV60331835, COSV60369370; called by muse, mutect2, varscan2
